Surgical pathology report (de-identified scan), TCGA case TCGA-85-8351, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8351-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

	Case ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 4.5 x 3.5 x 3 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 2/12 positive for metastasis (Hilar 2/12) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Right- lower

Source: NCI Genomic Data Commons file 62260993-b2b0-4c1f-a365-1cfdb10357ae (TCGA-85-8351.7D10178F-B714-46BE-A0F8-D2A03ABB0478.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).